CCDI case PBCJIG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ba5b359c-077b-4261-ad29-a9e8e461d166

Demographics
Sex at birth: male.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.2 years (4,441 days).

Biospecimens (3 samples)
- Sample 0DU07C: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU07K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DU090: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
